Somatic mutation profile of tumor specimen C3L-00447-02 (aliquot CPT0006900009) from CPTAC case C3L-00447, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 35.1 years (12,822 days).
Specimen C3L-00447-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0beeb908-f954-4798-85b1-f205205ee803.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00447-31 (Blood Derived Normal), aliquot CPT0002760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5f1e9d7-6fe3-480f-8647-9f53a58b4a87

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Intron 3, Nonsense Mutation 3, 3'UTR 1, 3'Flank 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 120/290 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs397516444, CM951291, CM951292, COSV56546524, COSV56553028, COSV56557871; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRF5 | c.2419G>A p.V807I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs558626782, COSV99345320, COSV99346143; called by muse, varscan2
- ANKRD53 | c.1561C>A p.P521T | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99721418; called by muse, mutect2
- CPNE7 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.156); catalogued as rs764118471, COSV99254901; called by muse, mutect2, varscan2
- HMG20A | c.1016G>C p.R339P | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs776151929, COSV100287599, COSV60311492; called by muse, mutect2, varscan2
- MFSD3 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as rs1341476589; called by muse, mutect2, varscan2
- OR2A14 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 21/380 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as rs201108825; called by muse, mutect2
- SUN5 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs929302638; called by muse, mutect2, varscan2
- ABCB6 | c.148T>A p.C50S | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ACBD3 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELF5 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- DAOA | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 60/246 reads (24%) | called by muse, mutect2, varscan2
- DGKB | c.1926_1927insT p.E643* | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, pindel
- DNAH12 | c.5394C>A p.F1798L (on ENST00000351747; = p.F1817L on NM_001366028.2) | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated (0.84); PolyPhen benign (0.089); called by muse, mutect2
- DPH1 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 43/130 reads (33%) | called by muse, mutect2, varscan2
- DUSP22 | c.263+2_263+16del p.X88_splice | Splice Site (DEL) | VAF 34/228 reads (15%) | called by mutect2, pindel
- FSTL4 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 107/359 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRAMD1A | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF3C2 | c.2110C>T p.R704* | Nonsense Mutation (SNP) | VAF 66/247 reads (27%) | called by muse, mutect2, varscan2
- MEDAG | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RNPEPL1 | c.1319T>A p.F440Y | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TAS2R19 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 83/297 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZBTB6 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF189 | c.1221A>C p.K407N | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C1QTNF4 | c.69G>A p.P23= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs754704315, COSV56782761; called by muse, mutect2, varscan2
- DNAJC25 | c.540A>G p.T180= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs776791144; called by muse, varscan2
- IFIT3 | c.333A>T p.S111= | Silent (SNP) | VAF 42/136 reads (31%) | called by muse, mutect2, varscan2
- LGI1 | c.969T>C p.D323= | Silent (SNP) | VAF 34/116 reads (29%) | called by muse, mutect2, varscan2
- LMTK2 | c.1341C>T p.L447= | Silent (SNP) | VAF 59/161 reads (37%) | catalogued as rs375715976; called by muse, mutect2, varscan2
- PTPRK | c.1395C>G p.L465= | Silent (SNP) | VAF 85/226 reads (38%) | catalogued as rs1294583233; called by muse, mutect2, varscan2
- TP53I11 | c.444T>A p.T148= | Silent (SNP) | VAF 46/164 reads (28%) | called by muse, mutect2, varscan2
- ACTRT3 | chr3:169764644 C>T | 3'Flank (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- DNAI4 | c.1097-539C>T | Intron (SNP) | VAF 54/182 reads (30%) | called by muse, varscan2
- EIF4A1 | c.515-147C>T | Intron (SNP) | VAF 37/88 reads (42%) | catalogued as rs1275963423; called by muse, mutect2, varscan2
- SLC22A8 | c.885+79C>T | Intron (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- XIRP2 | c.*656A>T | 3'UTR (SNP) | VAF 63/226 reads (28%) | called by muse, mutect2, varscan2
